Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A8NH, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A8NH-01A (Primary Tumor).

[page 1 of 3]
ICD O-3

Adenocarcinoma NOS 8140/3
Site ^{C64F} Esophagus, distal third C15.5
path Gastroesophageal junction C16.0

9/21/14

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

-year-old male with distal esophageal mass showing high grade dysplasia changes suspicious for invasive cancer. Combined hiatal hernia. 1.5 cm left basilar lung nodule, common bile duct dilatation and 2-3 cm left renal lesion suspicious for renal cell carcinoma. ERCP in showed ampullary adenoma.

PROCEDURE:

VERIFIED BY:

1. "Left thoracic inlet tracheoesophageal groove". 1.9 x 1.7 x 0.6 cm lobulated, firm, white nodule. Bisected.
- 1A. Frozen section control.
- 1B. Remainder.
2. "Retroportal lymph node". Two tan-brown soft tissue fragments, measuring 1.3 x 1.0 x 0.5 cm and 1.2 x 0.7 x 0.5 cm. Both bisected and submitted in cassettes 2A-B.

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 3
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

3. "Gallbladder". A 12.0 cm gallbladder, 4.5 cm in diameter with pink-purple, unremarkable serosal surface. The gallbladder is filled with amber bile and has a velvety, red-brown, unremarkable mucosa. Representative pieces from mucosa and cystic duct submitted in cassette 3.

4. "Esophagus and proximal stomach". An 8.0 cm esophagus, 2.3 cm in diameter with attached 5.4 cm proximal stomach, closed at both ends with staple lines. The esophageal mucosa is flattened, pink-gray with a 3.5 x 1.6 cm fungating, partially ulcerated, tan-brown lesion, 3.3 cm from the proximal margin of resection. At the level of the gastroesophageal junction, there is another 2.2 x 1.6 cm fungating, tan-brown lesion, 2.5 cm from the distal margin of resection. Both lesions are raised 1.2 cm from the mucosal surface of the specimen. Deep radial margin inked black. The mucosal lesions extend grossly to the level of the muscularis, but do not penetrate into the surrounding fat. It appears that the lesions may be connected at a level deep to the mucosa. Distal margin of resection inked blue. The surrounding fibroadipose tissue contains multiple lymph nodes, the largest of which appears grossly involved.

4A-B. Proximal mucosal lesion with deepest extension.

4C-D. Distal mucosal lesion with deepest extension. 4C contains interface between proximal and distal lesions.

4E. Distal margin of resection.

4F. Uninvolved gastric and esophageal mucosa.

4G-H. Largest lymph node.

4I-J. Two bisected lymph nodes each. One node has been inked blue in each case.

4K-L. Four lymph nodes each.

5. "Cervical esophageal margin". A 1.3 cm segment of esophagus, 2.0 cm in diameter, closed at one end with a staple line. Cross section submitted in one cassette.

FROZEN SECTION REPORT: .

1A. Lymph node with metastatic adenocarcinoma.

I, _____ have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section report.

PROCEDURE:

VERIFIED BY:

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Adenocarcinoma

If adenocarcinoma, is it arising in: G-E junction otherwise not specified

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 4
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

Depth of invasion: Muscularis propria

Number of positive lymph nodes, the total number sampled is irrelevant: 6

Extranodal metastasis: Unknown

Pattern of invasion: Infiltrative

Esophageal and gastric resection margins involved: No

Deep resection margin involved: No

TNM classification: T1N1MX

PROCEDURE:

VERIFIED BY:

1. Lymph node, "left thoracic inlet tracheoesophageal groove", excision: One lymph node positive for metastatic carcinoma (1/1).
2. Lymph node, "retroportal lymph node", excision: Two lymph nodes negative for neoplasm (0/2).
3. Gallbladder, resection: Chronic cholecystitis.
- 4-5. Esophagus, resection: Invasive adenocarcinoma, poorly differentiated, 5.7 cm, abutting the muscularis propria. Lymphatic invasion present. Margins negative. Please see template.

I, _____ D., the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

Source: NCI Genomic Data Commons file e909bff0-1456-4906-ad00-b33362f5f584 (TCGA-L5-A8NH.54F5151E-0008-40D7-9BD6-67AA7AC4E804.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).